Somatic mutation profile of tumor specimen TCGA-85-7696-01A (aliquot TCGA-85-7696-01A-11D-2122-08) from TCGA case TCGA-85-7696, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.1 years (23,413 days).
Specimen TCGA-85-7696-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0aad412c-18e8-47f5-af34-3bbbba9c2d77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-7696-10A (Blood Derived Normal), aliquot TCGA-85-7696-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30279e13-a725-482f-8d3b-d22176ca91bf

The open-access MAF lists 226 somatic variants for this specimen: 163 protein-altering or splice-affecting, 62 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 62, Nonsense Mutation 10, Frame Shift Del 5, Splice Site 3, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as rs775248597, CD088501, COSV99591936; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 32/48 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.665C>A p.A222E | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100383497; called by muse, mutect2, varscan2
- AC098582.1 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199802317, COSV52026263, COSV99985244; called by muse, varscan2
- ADCY1 | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99812904; called by muse, mutect2
- ADCY8 | c.1865C>A p.S622Y | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV99654351; called by muse, mutect2, varscan2
- ADRA1A | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs140512348, COSV99372231; called by muse, mutect2, varscan2
- ALPI | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99786173; called by muse, mutect2, varscan2
- ALPK3 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV99360476; called by muse, mutect2, varscan2
- ANKRD12 | c.1496G>A p.R499K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); catalogued as COSV100042106; called by muse, mutect2, varscan2
- AP5M1 | c.313A>T p.I105L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs755332047, COSV99841363; called by muse, mutect2, varscan2
- APBB1IP | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772305627, COSV100882261; called by muse, mutect2, varscan2
- ARHGAP33 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs759423493, COSV99140036; called by mutect2, varscan2
- ARHGAP35 | c.1750C>G p.R584G | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs750559194, COSV101351708; called by muse, mutect2, varscan2
- ART4 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99966986; called by muse, mutect2, varscan2
- ASCC3 | c.6260A>G p.Q2087R | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100976924; called by muse, mutect2, varscan2
- ASPHD2 | c.1001-1G>C p.X334_splice | Splice Site (SNP) | VAF 185/300 reads (62%) | catalogued as COSV99313606; called by muse, mutect2, varscan2
- ATP13A5 | c.2126G>A p.S709N | Missense Mutation (SNP) | VAF 116/328 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV100665722; called by muse, mutect2, varscan2
- BFAR | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1170085145, COSV99902462; called by muse, mutect2, varscan2
- BRWD1 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100314125; called by muse, mutect2, varscan2
- BTBD7 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV100108219; called by muse, mutect2, varscan2
- C1orf127 | c.1704C>A p.S568R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100983517, COSV65437050; called by muse, mutect2, varscan2
- C2orf16 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs770708739, COSV101284409; called by muse, mutect2, varscan2
- C3 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as COSV99837248; called by muse, mutect2, varscan2
- C3orf18 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV100597221; called by muse, mutect2, varscan2
- CALN1 | c.625G>T p.A209S (on ENST00000329008 / NM_001017440.3; = p.A251S on NM_031468.4) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100209324, COSV61140975; called by muse, mutect2, varscan2
- CDH17 | c.75del p.K26Sfs*6 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as COSV50325644; called by mutect2, pindel, varscan2
- CDKL5 | c.2768G>T p.R923L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV101183851, COSV66107237; called by muse, mutect2, varscan2
- CELSR3 | c.1709C>G p.T570S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV99375014; called by muse, mutect2, varscan2
- CEP63 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100133109; called by muse, mutect2, varscan2
- CERS4 | c.643G>T p.V215L | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.868); catalogued as rs769711560, COSV99250838; called by muse, mutect2
- CHD2 | c.1825A>T p.I609F | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.525); catalogued as COSV101245998; called by muse, mutect2, varscan2
- COL1A2 | c.2149G>A p.V717I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs1562905162, COSV99801109; called by muse, mutect2, varscan2
- COPS4 | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV100018847; called by muse, mutect2, varscan2
- CRYBG1 | c.2774T>C p.L925P | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV100954626; called by muse, mutect2, varscan2
- CSMD1 | c.8007G>A p.W2669* (on ENST00000520002; = p.W2668* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 20/146 reads (14%) | catalogued as COSV100153737; called by muse, mutect2, varscan2
- CSMD3 | c.9356C>T p.T3119I (on ENST00000297405 / NM_001363185.1; = p.T2950I on NM_052900.3) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as COSV99847730; called by muse, mutect2, varscan2
- CTR9 | c.1123T>A p.Y375N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100797535; called by muse, mutect2, varscan2
- DENND1A | c.2911A>G p.R971G | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.104); catalogued as rs150591766, COSV101012328; called by muse, mutect2, varscan2
- DNAH8 | c.10087G>A p.E3363K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100547240; called by muse, mutect2, varscan2
- DOCK10 | c.4628G>C p.R1543T | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99291649; called by muse, mutect2, varscan2
- EDC4 | c.2270G>A p.G757D | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.382); catalogued as COSV100197789; called by muse, mutect2, varscan2
- EFNB2 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.786); catalogued as rs1368423495, COSV99808949; called by muse, mutect2, varscan2
- EIF3D | c.274G>C p.A92P | Missense Mutation (SNP) | VAF 124/145 reads (86%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV99341762; called by muse, mutect2, varscan2
- ESRRG | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV100753897; called by muse, mutect2, varscan2
- FAM47C | c.2111C>A p.P704Q | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.945); catalogued as COSV100792948; called by muse, mutect2, varscan2
- FAT1 | c.6880G>T p.E2294* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as COSV101499647, COSV71673856; called by muse, mutect2, varscan2
- FCRL3 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV100943549; called by muse, mutect2, varscan2
- FSCB | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV100469888; called by muse, mutect2, varscan2
- GALNT13 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67219464, COSV67229690; called by muse, mutect2, varscan2
- GAREM1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs138720497; called by muse, mutect2, varscan2
- GFOD2 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV99263725; called by muse, mutect2, varscan2
- GLDC | c.2314G>A p.V772M | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100394602; called by muse, mutect2, varscan2
- GPHB5 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs746503469, COSV58485880; called by muse, mutect2, varscan2
- GRIN2A | c.2935G>T p.V979L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.109); catalogued as COSV100411078; called by muse, mutect2, varscan2
- GRK5 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV101230550, COSV67313710; called by muse, mutect2, varscan2
- GRM8 | c.1358G>A p.G453D | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV100286128; called by muse, mutect2, varscan2
- HCN1 | c.2572C>A p.P858T | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV100302338, COSV57520122; called by muse, mutect2, varscan2
- HECW1 | c.4351G>T p.G1451C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101224302, COSV67827012; called by muse, varscan2
- HMCN1 | c.12799G>A p.G4267R | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs747336634, COSV99635810; called by muse, mutect2, varscan2
- HOXB4 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100203854; called by muse, mutect2, varscan2
- IGFBP3 | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV51873620; called by muse, mutect2, varscan2
- IGKV1-12 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 76/508 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs553709659; called by muse, mutect2, varscan2
- IGSF1 | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT tolerated (0.56); PolyPhen benign (0.048); catalogued as COSV100812333; called by muse, mutect2, varscan2
- INPP4A | c.2671C>T p.R891W (on ENST00000074304 / NM_001134224.1; = p.R852W on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50815476; called by muse, mutect2
- INTS4 | c.1158G>C p.E386D | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV101417279; called by muse, mutect2, varscan2
- IQCH | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100246345; called by muse, mutect2, varscan2
- ITCH | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.988); catalogued as COSV99393175; called by muse, mutect2, varscan2
- KCNG2 | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100302111, COSV60269221; called by muse, mutect2, varscan2
- KCNH8 | c.2419C>A p.P807T | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV100111045, COSV60470490; called by muse, mutect2, varscan2
- KCNJ3 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99716505; called by muse, mutect2, varscan2
- KCNT1 | c.110+1G>A p.X37_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as rs780331569, COSV100040496; called by muse, mutect2, varscan2
- KIF2B | c.500A>T p.Q167L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99276230; called by muse, mutect2, varscan2
- KRT84 | c.1317G>T p.Q439H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99231054; called by muse, mutect2, varscan2
- LAMA2 | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV101370834; called by muse, mutect2, varscan2
- LAMC3 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100736091; called by muse, mutect2
- LILRA4 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV99393386; called by muse, mutect2, varscan2
- LRP8 | c.2705G>C p.W902S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV100036913; called by mutect2, varscan2
- LRRN1 | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100076601; called by muse, mutect2
- LRTM2 | c.438C>A p.D146E | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99766515; called by muse, mutect2, varscan2
- LYST | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 24/150 reads (16%) | catalogued as CM1514509, COSV101090302; called by muse, mutect2, varscan2
- MCM3AP | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99387526; called by muse, mutect2, varscan2
- MID1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM070997, COSV100452720; called by muse, mutect2, varscan2
- MROH9 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV100883056; called by muse, mutect2, varscan2
- MTUS1 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 39/118 reads (33%) | catalogued as COSV100030042; called by muse, mutect2, varscan2
- MUC17 | c.3624C>A p.S1208R | Missense Mutation (SNP) | VAF 117/795 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100075055; called by muse, mutect2, varscan2
- MXRA5 | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs183322867, COSV54243662, COSV99479043; called by muse, mutect2, varscan2
- MYBPC1 | c.694A>T p.T232S (on ENST00000550270 / NM_206820.2; = p.T257S on NM_002465.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100638279; called by muse, mutect2, varscan2
- MYBPC1 | c.695C>T p.T232I (on ENST00000550270 / NM_206820.2; = p.T257I on NM_002465.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100638280; called by muse, mutect2, varscan2
- NAV3 | c.2572G>C p.D858H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99895670; called by muse, mutect2, varscan2
- NFKB2 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as rs758763622, COSV51870511; called by muse, mutect2, varscan2
- NID1 | c.2716G>T p.V906L | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99938336; called by muse, mutect2, varscan2
- NLRP14 | c.946A>T p.K316* | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | catalogued as COSV100205440; called by muse, mutect2, varscan2
- NPAP1 | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as COSV100276200, COSV61506086; called by muse, mutect2, varscan2
- NRG3 | c.1064A>G p.E355G | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100932564; called by muse, mutect2, varscan2
- NXPE1 | c.1405C>A p.P469T (on ENST00000424269; = p.P327T on NM_152315.5) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52628325, COSV99321031; called by muse, mutect2, varscan2
- ODF3 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100285343; called by muse, mutect2, varscan2
- OR11L1 | c.131T>G p.V44G | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV100869493; called by muse, mutect2, varscan2
- OR13D1 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as COSV100598754; called by muse, mutect2, varscan2
- OR4C6 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as rs746616835, COSV58603591, COSV58605102, COSV58606600; called by muse, mutect2, varscan2
- OR4K17 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100210799; called by muse, mutect2
- OR5D16 | c.173A>T p.H58L | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs775561489, COSV101004145; called by muse, mutect2, varscan2
- OR5T3 | c.738G>C p.R246S | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV100282937, COSV57382253; called by muse, mutect2, varscan2
- OR8G1 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100422671; called by muse, mutect2, varscan2
- OSBPL3 | c.2323A>G p.M775V | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs978835989, COSV100514550; called by muse, mutect2, varscan2
- PAPPA2 | c.4336C>T p.L1446F | Missense Mutation (SNP) | VAF 89/175 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100868651; called by muse, mutect2, varscan2
- PCDHA3 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV100974145; called by muse, mutect2, varscan2
- PDCD11 | c.1009C>G p.R337G | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.169); catalogued as COSV100874418; called by muse, mutect2
- PDE4DIP | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 96/165 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1360131650, COSV100521767; called by muse, mutect2, varscan2
- PHACTR3 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100733210, COSV63033263; called by muse, mutect2, varscan2
- PIGG | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99574342; called by muse, mutect2, varscan2
- PIGK | c.1068C>G p.H356Q | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100892243; called by muse, mutect2, varscan2
- PLEKHA7 | c.1944T>A p.H648Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.371); catalogued as COSV100850424; called by muse, mutect2, varscan2
- PRDM9 | c.1797G>T p.Q599H | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs879036362, COSV99691267; called by muse, mutect2, varscan2
- PRKN | c.1283dup p.N428Kfs*141 | Frame Shift Ins (INS) | VAF 64/172 reads (37%) | catalogued as rs758718482; called by mutect2, varscan2
- PRRX1 | c.246C>G p.D82E | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99510336; called by muse, mutect2
- PSMG1 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs1194672826, COSV100314122; called by muse, mutect2, varscan2
- RBM5 | c.289A>G p.S97G | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100762495; called by muse, mutect2, varscan2
- RC3H1 | c.3122G>A p.R1041Q | Missense Mutation (SNP) | VAF 97/436 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.041); catalogued as rs202128105, COSV51198923; called by muse, mutect2, varscan2
- RCL1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.096); catalogued as rs115216700, COSV67755672; called by muse, mutect2, varscan2
- RGS22 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100693811, COSV62657629; called by muse, mutect2, varscan2
- RHAG | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as rs1183221106, COSV100006875; called by muse, mutect2, varscan2
- SACS | c.12233G>T p.R4078L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV101207730; called by muse, mutect2, varscan2
- SDK2 | c.2039C>T p.T680I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs764295267, COSV101168619; called by muse, mutect2, varscan2
- SH3RF2 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768036; called by muse, mutect2, varscan2
- SIK3 | c.1255G>A p.V419I (on ENST00000445177 / NM_001366686.2; = p.V425I on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs765423099, COSV52618297; called by muse, mutect2, varscan2
- SIN3A | c.2315C>T p.P772L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100845233; called by muse, mutect2, varscan2
- SLC15A2 | c.1261C>A p.L421M | Missense Mutation (SNP) | VAF 40/325 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.475); catalogued as COSV99815114; called by muse, mutect2, varscan2
- SLC20A2 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100646224; called by muse, mutect2, varscan2
- SLC26A3 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as rs1438356683, COSV100385298, COSV60640493; called by muse, mutect2, varscan2
- SLC45A2 | c.655T>A p.F219I | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99673130; called by muse, mutect2
- SLIT1 | c.3925G>C p.G1309R | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV56599792, COSV99822540; called by muse, mutect2, varscan2
- SORL1 | c.4177G>A p.D1393N | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428947446, COSV52758134, COSV99495478; called by muse, mutect2
- SOX7 | c.332A>C p.N111T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs766533156, COSV100449176; called by muse, mutect2, varscan2
- SPG11 | c.5091G>C p.E1697D | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.465); catalogued as COSV99969662; called by muse, mutect2
- SPTA1 | c.3514G>A p.A1172T | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0.272); catalogued as rs767818064, COSV100935578; called by muse, mutect2, varscan2
- STAB2 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | catalogued as rs758124266, COSV101186311, COSV66345395; called by muse, mutect2, varscan2
- SULF1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99484360; called by muse, mutect2, varscan2
- SYNE1 | c.26210G>T p.G8737V (on ENST00000367255 / NM_182961.4; = p.G8689V on NM_033071.3) | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs772814249, COSV54935271, COSV99578787; called by muse, mutect2, varscan2
- SYNE1 | c.8819C>G p.T2940R (on ENST00000367255 / NM_182961.4; = p.T2947R on NM_033071.3) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV54966342, COSV99578789; called by muse, mutect2, varscan2
- TAB2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV99645109; called by muse, mutect2, varscan2
- TBC1D9B | c.3211C>T p.R1071C (on ENST00000356834 / NM_198868.3; = p.R1054C on NM_015043.4) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs144624491; called by muse, mutect2, varscan2
- TECTA | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50689042, COSV99881561; called by muse, mutect2, varscan2
- TENM1 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.994); catalogued as COSV100950964; called by muse, mutect2, varscan2
- TENM4 | c.2897G>A p.G966D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53665661; called by muse, mutect2
- TPO | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100222157; called by muse, mutect2, varscan2
- TRDN | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.632); catalogued as COSV100523399; called by muse, mutect2
- TSPYL2 | c.1084C>G p.H362D | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as COSV100212423; called by muse, mutect2, varscan2
- TTN | c.12719C>A p.A4240D (on ENST00000591111; = p.A4194D on NM_003319.4) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV59911042; called by muse, mutect2, varscan2
- UBASH3A | c.1577T>A p.L526H | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99369974; called by muse, mutect2, varscan2
- UNC13A | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53208213; called by muse, mutect2, varscan2
- VAX1 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as COSV99524423; called by muse, mutect2
- WEE2 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 89/395 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs769118966, COSV101187690; called by muse, mutect2, varscan2
- ZNF22 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100026667; called by muse, mutect2, varscan2
- ZNF536 | c.2777T>C p.V926A | Missense Mutation (SNP) | VAF 107/393 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); catalogued as COSV100835898; called by muse, mutect2, varscan2
- ZNF831 | c.3524C>A p.P1175H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64038892; called by muse, mutect2, varscan2
- ERMARD | c.1266dup p.A423Cfs*5 | Frame Shift Ins (INS) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.207+1del p.X69_splice | Splice Site (DEL) | VAF 25/98 reads (26%) | called by mutect2, pindel, varscan2
- LRRC40 | c.927_933del p.L310Gfs*8 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- SAMD3 | c.1456del p.Q486Kfs*6 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | called by mutect2, pindel, varscan2
- SDR42E1 | c.703del p.A235Pfs*5 | Frame Shift Del (DEL) | VAF 50/153 reads (33%) | called by mutect2, pindel, varscan2
- SLC22A15 | c.944+1del | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- AIM2 | c.366T>C p.R122= | Silent (SNP) | VAF 45/161 reads (28%) | catalogued as COSV100931152; called by muse, mutect2, varscan2
- C16orf46 | c.894C>T p.C298= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV100215473; called by muse, mutect2, varscan2
- CALD1 | c.2370C>A p.P790= (on ENST00000361675 / NM_033138.4; = p.P535= on NM_004342.7) | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as COSV100724576; called by muse, mutect2
- CCT8 | c.132T>C p.R44= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99726166; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3090A>T p.T1030= | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as COSV100575742; called by muse, mutect2, varscan2
- CLPX | c.693G>A p.R231= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs777759853, COSV100269648; called by muse, mutect2, varscan2
- CPA5 | c.1059G>A p.A353= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs147880943; called by muse, mutect2, varscan2
- DCAF8L1 | c.276G>A p.P92= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs374309786, COSV71595318; called by muse, mutect2, varscan2
- DLX6 | c.840C>T p.S280= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99142515; called by muse, mutect2, varscan2
- FKBP15 | c.546C>G p.L182= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99439806; called by muse, mutect2, varscan2
- FMNL2 | c.384A>G p.E128= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99980878; called by muse, mutect2, varscan2
- GLRA1 | c.639C>G p.P213= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as COSV99199688; called by muse, mutect2, varscan2
- GRPR | c.978C>T p.S326= | Silent (SNP) | VAF 72/99 reads (73%) | catalogued as COSV100977703; called by muse, mutect2, varscan2
- HOXB3 | c.1164G>T p.G388= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as rs763094017, COSV100290816; called by muse, mutect2, varscan2
- ICA1 | c.1353C>T p.D451= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV99655913; called by muse, mutect2, varscan2
- IDH3B | c.1086C>T p.D362= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV100250347; called by muse, mutect2, varscan2
- IGKV1D-42 | c.96C>T p.F32= | Silent (SNP) | VAF 52/123 reads (42%) | catalogued as rs774275259; called by muse, mutect2, varscan2
- IRF2BP1 | c.1608G>A p.K536= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100139017; called by muse, mutect2, varscan2
- IRS4 | c.906C>T p.I302= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as COSV64532702; called by muse, mutect2, varscan2
- KLHL1 | c.1563C>T p.N521= | Silent (SNP) | VAF 55/119 reads (46%) | catalogued as COSV64785104; called by muse, mutect2, varscan2
- KRTAP5-10 | c.585C>G p.P195= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs758747910, COSV100924167, COSV64795798; called by muse, mutect2, varscan2
- LAIR2 | c.458G>A p.*153= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as COSV100003448; called by muse, mutect2, varscan2
- NCKIPSD | c.1011C>T p.I337= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99584257; called by muse, mutect2, varscan2
- NCS1 | c.174C>T p.F58= | Silent (SNP) | VAF 46/159 reads (29%) | catalogued as rs148178859; called by muse, mutect2, varscan2
- NIN | c.2337T>A p.L779= | Silent (SNP) | VAF 29/172 reads (17%) | catalogued as COSV99815293; called by muse, mutect2, varscan2
- NMRAL1 | c.822G>A p.L274= | Silent (SNP) | VAF 55/168 reads (33%) | catalogued as COSV99361940; called by muse, mutect2, varscan2
- NR5A1 | c.780G>A p.A260= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs374900251; called by muse, mutect2, varscan2
- NRIP1 | c.2565C>A p.V855= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100013108, COSV59657187; called by muse, mutect2, varscan2
- NTSR1 | c.1209C>A p.S403= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100980717; called by muse, mutect2, varscan2
- OLFML2A | c.1958G>A p.*653= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV99992896; called by mutect2, varscan2
- OR11L1 | c.759G>T p.G253= | Silent (SNP) | VAF 70/143 reads (49%) | catalogued as COSV100869492; called by muse, mutect2, varscan2
- OR2A4 | c.51C>T p.P17= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs1399240639, COSV100199643; called by muse, mutect2, varscan2
- OR2T27 | c.30C>T p.A10= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs148569814; called by muse, mutect2, varscan2
- OR4D9 | c.492C>T p.L164= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as COSV100259999, COSV61435020; called by muse, mutect2, varscan2
- OR52J3 | c.297T>C p.C99= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100984940; called by muse, mutect2, varscan2
- OR5H2 | c.843C>T p.V281= | Silent (SNP) | VAF 61/100 reads (61%) | catalogued as COSV100788738, COSV100788832; called by muse, mutect2, varscan2
- OR6B2 | c.738C>T p.T246= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs757356113, COSV53156979, COSV99401758; called by muse, mutect2, varscan2
- OR9G1 | c.459T>C p.I153= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as COSV100380559; called by muse, mutect2, varscan2
- PAPPA2 | c.1353G>A p.A451= | Silent (SNP) | VAF 42/248 reads (17%) | catalogued as rs766792383, COSV62775861; called by muse, mutect2, varscan2
- PCDHAC1 | c.2106C>T p.F702= | Silent (SNP) | VAF 9/144 reads (6%) | catalogued as rs1448389331, COSV53855580; called by muse, mutect2
- PCDHB8 | c.1527A>G p.T509= | Silent (SNP) | VAF 69/197 reads (35%) | catalogued as rs781853336, COSV50853057; called by muse, mutect2, varscan2
- PCDHGA2 | c.1743C>T p.S581= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as rs1236734969, COSV53903996, COSV99548606; called by muse, mutect2, varscan2
- PDE3A | c.1044C>T p.A348= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs779242729, COSV100762804, COSV62969685; called by muse, mutect2, varscan2
- PDE6B | c.1386G>A p.E462= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs369946269; called by muse, mutect2, varscan2
- PEX5L | c.273G>A p.S91= | Silent (SNP) | VAF 83/411 reads (20%) | catalogued as rs1344594831, COSV99829241; called by muse, mutect2, varscan2
- PRUNE2 | c.6714T>A p.T2238= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100945138; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2088G>A p.Q696= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV54763158, COSV99770489; called by muse, mutect2, varscan2
- RBM28 | c.2034C>T p.G678= | Silent (SNP) | VAF 99/353 reads (28%) | catalogued as COSV99775931; called by muse, mutect2, varscan2
- SIX1 | c.90G>C p.L30= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs1402174239, COSV99903491; called by mutect2, varscan2
- SLC5A2 | c.1062G>T p.V354= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100393420; called by muse, mutect2, varscan2
- SLCO4A1 | c.2127C>T p.A709= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs1365764311, COSV99415129; called by muse, mutect2, varscan2
- TBRG4 | c.144C>T p.S48= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as COSV99345647; called by muse, mutect2, varscan2
- TCAF2 | c.1074G>T p.L358= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100633739; called by muse, mutect2, varscan2
- TECTA | c.5619A>T p.T1873= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV99881563; called by muse, mutect2, varscan2
- TEX15 | c.450G>A p.K150= (on ENST00000256246; = p.K533= on NM_001350162.2) | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV99822133; called by muse, mutect2, varscan2
- TM9SF2 | c.186A>G p.L62= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs372856289; called by muse, mutect2, varscan2
- TMEM132D | c.870G>T p.V290= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV101398347; called by muse, mutect2, varscan2
- TPTE | c.696G>A p.R232= (on ENST00000618007 / NM_199261.4; = p.R214= on NM_199259.4) | Silent (SNP) | VAF 36/440 reads (8%) | catalogued as rs756795446; called by muse, mutect2
- TPTE | c.942G>A p.Q314= (on ENST00000618007 / NM_199261.4; = p.Q296= on NM_199259.4) | Silent (SNP) | VAF 70/279 reads (25%) | catalogued as rs375679452; called by muse, mutect2, varscan2
- USP19 | c.3066C>G p.V1022= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV60045014; called by muse, mutect2, varscan2
- ZBTB41 | c.888G>A p.E296= | Silent (SNP) | VAF 50/210 reads (24%) | catalogued as rs1557990302, COSV100963444; called by muse, mutect2, varscan2
- ZFHX4 | c.9354G>A p.L3118= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99267677; called by muse, mutect2, varscan2
- C17orf58 | c.103+14C>T | Intron (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100558755; called by muse, mutect2, varscan2
